CCDI case PBBNSG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/b4ac75dc-f83c-4f35-b8ce-6a842fe2214a

Demographics
Sex at birth: male; Race: black or african american; Vital status: Alive.

Diagnoses (1)
1. Ganglioglioma, NOS: ICD-O-3 morphology code: 9505/1; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 6.5 years (2,387 days).

Biospecimens (3 samples)
- Sample 0DNP4B: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DNP4D: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DNP4F: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
